Somatic mutation profile of tumor specimen MP2PRT-PAUVRK-TMP1-A (aliquot MP2PRT-PAUVRK-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUVRK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,376 days).
Specimen MP2PRT-PAUVRK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d046456b-3025-4007-9b83-18774ed741bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUVRK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUVRK-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7e630d6-1bbc-4b04-a3da-d289b887cc7d

The open-access MAF lists 11 somatic variants for this specimen: 11 protein-altering or splice-affecting.
By variant classification: Missense Mutation 10, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.3836+1G>A p.X1279_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as rs200782888, CS056749, COSV52117332; ClinVar: pathogenic; called by muse, varscan2
- FLT3 | c.1987A>C p.K663Q | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1057520026, COSV54065828; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF37 | c.1585C>T p.R529W | Missense Mutation (SNP) | VAF 52/397 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201632067; called by muse, mutect2, varscan2
- CACNA2D3 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.85); catalogued as rs764440125, COSV55512686; called by muse, mutect2, varscan2
- HECTD2 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs749422558, COSV104402083; called by muse, mutect2, varscan2
- KCNK2 | c.139C>T p.R47W (on ENST00000444842 / NM_001017425.3; = p.R32W on NM_014217.4) | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1217299174; called by muse, mutect2, varscan2
- SALL3 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 205/756 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1026536209; called by muse, mutect2, varscan2
- TNFSF18 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 83/261 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.204); catalogued as rs142512692; called by muse, mutect2, varscan2
- ARHGAP6 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 226/512 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNHD1 | c.6173T>G p.V2058G | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TRBV20OR9-2 | c.28A>G p.R10G | Missense Mutation (SNP) | VAF 38/348 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.025); called by muse, mutect2, varscan2
